CGCI case BLGSP-71-22-00332 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fcd39a3f-169a-463f-8153-17ebc1b218a8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of abdomen; Classification of tumor: primary; Age at diagnosis: 8.4 years (3,062 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,099 days (3.0 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone, NOS / Central nervous system / Small intestine / Kidney, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ANHL1131 (Group C + rituximab); Days to treatment start: 1 day; Days to treatment end: 173 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 173 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 30.
- Days to follow up: 1,099 days (3.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2: Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Ki67: Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 2317 [Blood test normal range upper: 237].
- Epstein-Barr Virus (ISH) 75 (Positive).

Other clinical attributes
- Day 0: Weight: 34 kg; Height: 150 cm; BMI: 15.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-22-00332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Soft Tissue; Preservation method: Frozen; Days to sample procurement: 0 days; Tissue collection type: Prospective.
  Slide BLGSP-71-22-00332-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 75; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-22-00332-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 15; Percent stromal cells: 40; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-22-00332-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-22-00332-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 1 day; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: No.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone; Extranodal involvement site: Epidural; Extranodal involvement site: Small Intestine; Extranodal involvement site: Kidney.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 2317; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
